Somatic mutation profile of tumor specimen TCGA-85-A50Z-01A (aliquot TCGA-85-A50Z-01A-21D-A25L-08) from TCGA case TCGA-85-A50Z, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.3 years (20,941 days).
Specimen TCGA-85-A50Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66e22bc9-def6-4e3b-827e-86a6c80a14aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-A50Z-10A (Blood Derived Normal), aliquot TCGA-85-A50Z-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4a582e9-b16b-4b55-8a8e-fb903ad8c7f3

The open-access MAF lists 496 somatic variants for this specimen: 374 protein-altering or splice-affecting, 114 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 327, Silent 114, Nonsense Mutation 22, Frame Shift Del 10, Splice Site 9, Splice Region 4, RNA 4, Frame Shift Ins 2, 5'UTR 1, 3'UTR 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.801+1G>T p.X267_splice | Splice Site (SNP) | VAF 14/77 reads (18%) | hotspot (GDC flag); catalogued as CD011189, CS002685, CS992481, COSV64296194, COSV64297522; called by muse, mutect2, varscan2
- TP53 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.526A>T p.T176S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as COSV99712812; called by muse, mutect2, varscan2
- ABCB10 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV100747923; called by muse, mutect2, varscan2
- ABCB11 | c.3061A>T p.I1021F | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.134); catalogued as COSV99792028; called by muse, mutect2
- ADAM2 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); catalogued as COSV55865564, COSV99697377; called by muse, mutect2, varscan2
- ADAMTS3 | c.2485G>C p.D829H | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV99710861; called by muse, mutect2, varscan2
- ADAR | c.850A>G p.T284A | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52722373; called by muse, mutect2, varscan2
- ADCY1 | c.1584G>T p.M528I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99811850; called by muse, mutect2, varscan2
- ADGRB1 | c.2358C>A p.F786L | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV100029550; called by muse, mutect2, varscan2
- ADGRB3 | c.911C>A p.S304* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV101000410, COSV65401204; called by muse, mutect2, varscan2
- ADGRG1 | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV101113402; called by muse, varscan2
- ADGRG7 | c.1742T>C p.V581A | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV99840908; called by muse, mutect2, varscan2
- ADGRL2 | c.1160G>T p.R387L | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs764875953, COSV99588522; called by muse, mutect2, varscan2
- AGMO | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.048); catalogued as COSV100694041; called by muse, mutect2, varscan2
- AHNAK | c.2221C>A p.H741N | Missense Mutation (SNP) | VAF 60/326 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV99947065; called by muse, mutect2, varscan2
- ALK | c.1045G>C p.V349L | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as rs370848188, COSV101201525, COSV101201856; called by muse, mutect2, varscan2
- AMY2B | c.127T>C p.C43R | Missense Mutation (SNP) | VAF 58/472 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781089141, COSV100796273; called by muse, mutect2, varscan2
- ANGEL2 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.923); catalogued as COSV100853940; called by muse, mutect2, varscan2
- AP3B2 | c.1522A>T p.I508F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99916404; called by muse, mutect2, varscan2
- APOB | c.7639G>C p.V2547L | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99265216; called by muse, mutect2, varscan2
- ARAP2 | c.1028T>C p.L343P | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV100394493; called by muse, mutect2, varscan2
- ARHGAP11A | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100853229; called by mutect2, varscan2
- ARHGAP11B | c.689G>T p.R230I | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.432); catalogued as COSV101451784; called by muse, mutect2, varscan2
- ARNT | c.1660G>T p.D554Y | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100591093; called by muse, mutect2, varscan2
- ARSG | c.914C>G p.P305R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV101477882, COSV101477889; called by muse, mutect2, varscan2
- ARV1 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.061); catalogued as COSV100048404, COSV59617716; called by muse, mutect2, varscan2
- ASB8 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100480630; called by muse, mutect2, varscan2
- ASXL1 | c.2261C>T p.T754I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV100038814; called by muse, mutect2, varscan2
- ATG3 | c.555A>T p.K185N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV51926780, COSV99344114; called by muse, mutect2, varscan2
- ATP13A2 | c.2900A>G p.D967G | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100454103; called by muse, mutect2, varscan2
- ATP1A3 | c.2771C>G p.A924G (on ENST00000545399 / NM_001256214.2; = p.A911G on NM_152296.5) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV100132209; called by muse, mutect2, varscan2
- ATP2C1 | c.1095A>G p.I365M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.142); catalogued as COSV100146633; called by muse, mutect2, varscan2
- BABAM2 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 16/119 reads (13%) | catalogued as COSV100567749; called by muse, mutect2, varscan2
- C2orf78 | c.2668C>A p.R890S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV101280875, COSV101280955; called by muse, mutect2
- CA1 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV99810127; called by muse, mutect2, varscan2
- CACNA1A | c.4555G>C p.E1519Q | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100802088, COSV64196136; called by muse, mutect2, varscan2
- CACNA2D4 | c.2077G>C p.D693H | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV99765509; called by muse, mutect2, varscan2
- CADM2 | c.652A>T p.M218L (on ENST00000407528 / NM_001167674.2; = p.M220L on NM_153184.4) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV67412502; called by muse, mutect2, varscan2
- CAMSAP1 | c.3482A>T p.H1161L | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV100409788; called by muse, mutect2, varscan2
- CAMSAP1 | c.2401C>G p.Q801E | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs749774202, COSV56719156, COSV56721419; called by muse, mutect2, varscan2
- CASP2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV100130973; called by muse, mutect2, varscan2
- CCDC73 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 17/133 reads (13%) | catalogued as COSV100067237, COSV58797856; called by muse, mutect2, varscan2
- CCL7 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as rs1460365152, COSV99565528; called by muse, mutect2
- CCR3 | c.631C>G p.P211A | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100656459, COSV100656838; called by muse, mutect2, varscan2
- CCT6A | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV99303410; called by muse, mutect2, varscan2
- CD109 | c.1507A>G p.R503G | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV99753406; called by muse, mutect2, varscan2
- CD163L1 | c.3353G>A p.R1118H | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.039); catalogued as rs200548297, COSV100549961; called by muse, mutect2
- CDH6 | c.107G>T p.R36M | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as COSV99418877; called by muse, mutect2, varscan2
- CENPJ | c.2815G>C p.E939Q | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV101121502; called by muse, mutect2, varscan2
- CEP43 | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV100835602, COSV62760335; called by muse, mutect2, varscan2
- CFAP92 | c.489G>A p.W163* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99414719; called by muse, mutect2
- CGN | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV99642217; called by muse, mutect2, varscan2
- CHMP3 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55685573, COSV99806644; called by muse, mutect2, varscan2
- CKAP5 | c.3089G>T p.R1030L | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100370713; called by muse, mutect2, varscan2
- CKM | c.442C>A p.R148S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV99675526; called by muse, mutect2, varscan2
- CLDN16 | c.702G>T p.R234S | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99290128; called by muse, mutect2, varscan2
- CLEC2D | c.461A>T p.Q154L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99324970; called by muse, mutect2, varscan2
- CLVS1 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.707); catalogued as COSV100369836, COSV100370711; called by muse, mutect2, varscan2
- COL11A2 | c.4960C>T p.P1654S (on ENST00000341947 / NM_080680.3; = p.P1547S on NM_080679.2) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.237); catalogued as COSV100553833; called by muse, mutect2, varscan2
- COL12A1 | c.2437+1G>T p.X813_splice | Splice Site (SNP) | VAF 31/270 reads (11%) | catalogued as COSV100485873; called by muse, mutect2, varscan2
- COL19A1 | c.3293G>T p.G1098V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100506117; called by muse, mutect2, varscan2
- COL1A2 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.03); catalogued as COSV99799482; called by muse, mutect2, varscan2
- CPED1 | c.92A>G p.Q31R | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100120543; called by muse, mutect2, varscan2
- CRACD | c.2015G>T p.R672L | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51716885, COSV99949113; called by muse, mutect2, varscan2
- CTNNA2 | c.1948C>A p.R650S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.325); catalogued as COSV100560199, COSV58141407; called by muse, mutect2, varscan2
- CTNND2 | c.3161C>A p.S1054Y | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV100475541, COSV58867038; called by muse, mutect2, varscan2
- CTTNBP2 | c.2699T>C p.V900A | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99353727; called by muse, mutect2, varscan2
- CUL4B | c.2404A>G p.I802V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1392017683, COSV100340428; called by muse, mutect2, varscan2
- CWH43 | c.1364A>G p.N455S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1349057717, COSV99893299; called by muse, mutect2, varscan2
- CX3CL1 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99136305; called by muse, mutect2, varscan2
- CYP4F11 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.102); catalogued as COSV99930816; called by muse, mutect2, varscan2
- DDIAS | c.496G>C p.V166L | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs781294605, COSV100231163, COSV61272874; called by muse, mutect2, varscan2
- DDX4 | c.1806A>T p.R602S | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100737488; called by muse, mutect2, varscan2
- DEPDC5 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99836319; called by muse, mutect2, varscan2
- DLGAP1 | c.593C>A p.S198Y | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV100229828; called by muse, mutect2, varscan2
- DLGAP4 | c.26C>A p.P9H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV100211119; called by muse, mutect2, varscan2
- DMBT1 | c.1550C>A p.T517N | Missense Mutation (SNP) | VAF 177/384 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100352790; called by muse, mutect2, varscan2
- DMXL2 | c.5770C>T p.P1924S | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs375382526; called by muse, mutect2, varscan2
- DNAH5 | c.10098A>T p.L3366F | Missense Mutation (SNP) | VAF 51/255 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99448791; called by muse, mutect2, varscan2
- DNAH5 | c.8526G>T p.W2842C | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99448794; called by muse, mutect2, varscan2
- DNAH5 | c.8525G>C p.W2842S | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99445642, COSV99448797; called by muse, mutect2, varscan2
- DNAH8 | c.13359C>G p.Y4453* | Nonsense Mutation (SNP) | VAF 21/110 reads (19%) | catalogued as COSV100544653; called by muse, mutect2, varscan2
- DNAI4 | c.2348C>A p.P783H | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100925489; called by muse, mutect2, varscan2
- DNAI4 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 22/122 reads (18%) | catalogued as COSV100590939; called by muse, mutect2, varscan2
- DPP4 | c.1052C>G p.T351S | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as COSV100858834; called by muse, mutect2, varscan2
- DPYSL5 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99982238; called by muse, mutect2, varscan2
- DSP | c.7450A>G p.K2484E | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.192); catalogued as rs1554109006, COSV101131248; called by muse, mutect2, varscan2
- DYRK4 | c.419G>T p.R140M | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs780631150, COSV99156124; called by muse, mutect2, varscan2
- ECT2 | c.329T>C p.M110T (on ENST00000392692 / NM_001349098.2; = p.M79T on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770694791, COSV99221246; called by muse, mutect2, varscan2
- ECT2 | c.2491A>G p.K831E (on ENST00000392692 / NM_001349098.2; = p.K800E on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV51688594, COSV99221249; called by muse, mutect2
- EHD1 | c.95A>T p.K32M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100276982; called by muse, mutect2, varscan2
- EML1 | c.1120G>T p.V374L | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV99214894; called by muse, mutect2
- ENAM | c.415T>A p.L139M | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.392); catalogued as COSV101253064; called by muse, mutect2, varscan2
- EPB41L1 | c.1166T>C p.M389T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99150239; called by muse, mutect2, varscan2
- EPB41L2 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV100440573, COSV61355168; called by muse, mutect2, varscan2
- EPHA10 | c.2046C>A p.S682R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV100361216; called by muse, mutect2, varscan2
- EPPK1 | c.5708C>A p.T1903K | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV101599817; called by muse, mutect2, varscan2
- ETNPPL | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV99625179; called by muse, mutect2, varscan2
- EVPL | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs765783983, COSV100044397, COSV56910778; called by muse, mutect2, varscan2
- EYS | c.1532C>A p.A511E | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.145); catalogued as COSV100676312, COSV60982676; called by muse, mutect2, varscan2
- F11 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99251472; called by muse, mutect2, varscan2
- FAM135A | c.2260A>T p.K754* (on ENST00000370479 / NM_001351599.1; = p.K541* on NM_020819.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 36/172 reads (21%) | catalogued as COSV52048919, COSV99525666; called by muse, mutect2, varscan2
- FAM47C | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.071); catalogued as rs782209571, COSV63725760, COSV63726126; called by muse, mutect2, varscan2
- FAM72A | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 60/368 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1215174783, COSV100367253; called by muse, mutect2, varscan2
- FAM83H | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV101186963; called by muse, mutect2, varscan2
- FAT4 | c.4174G>T p.A1392S | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101272268; called by muse, mutect2, varscan2
- FGD2 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV99236086; called by muse, mutect2, varscan2
- FHL5 | c.431C>A p.S144Y | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV100459344; called by muse, mutect2, varscan2
- FRZB | c.182C>A p.T61N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99717353; called by muse, mutect2, varscan2
- GABBR2 | c.746G>T p.R249L | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52292077; called by muse, mutect2
- GABRG1 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777361, COSV99777845; called by muse, mutect2, varscan2
- GAD2 | c.1352A>T p.D451V | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99393102; called by muse, mutect2, varscan2
- GALNT4 | c.7G>T p.V3L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV100544176; called by muse, mutect2, varscan2
- GALNTL6 | c.549G>C p.E183D | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101487736; called by muse, mutect2, varscan2
- GAS2L3 | c.1597C>G p.L533V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV57156132; called by muse, mutect2, varscan2
- GATAD2A | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.494); catalogued as COSV99390046; called by muse, mutect2, varscan2
- GGN | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.97); catalogued as COSV53056335; called by muse, mutect2
- GK | c.670G>C p.G224R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV100970836; called by muse, mutect2, varscan2
- GLIS1 | c.983G>C p.G328A | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100389865; called by muse, mutect2, varscan2
- GOLT1B | c.252G>C p.L84F | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV57554397; called by muse, mutect2, varscan2
- GPR31 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.048); catalogued as rs780751665, COSV100834128; called by muse, mutect2, varscan2
- GRAMD1B | c.331C>A p.L111I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100454637; called by muse, mutect2, varscan2
- GRIK3 | c.1326+1G>T p.X442_splice | Splice Site (SNP) | VAF 13/80 reads (16%) | catalogued as COSV100901859; called by muse, mutect2
- GRIK3 | c.1326G>T p.L442= | Splice Region (SNP) | VAF 14/79 reads (18%) | catalogued as COSV100901861; called by muse, mutect2, varscan2
- GRM7 | c.2317T>C p.Y773H | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100736192; called by muse, mutect2, varscan2
- HAPLN3 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100613705, COSV61370024; called by muse, mutect2, varscan2
- HCK | c.507G>T p.M169I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV99393977; called by muse, mutect2
- HEMGN | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV99412371; called by muse, mutect2, varscan2
- HES1 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51684402, COSV51684593, COSV99220395; called by muse, mutect2, varscan2
- HM13 | c.268T>A p.Y90N | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100159450; called by muse, mutect2, varscan2
- HMGCLL1 | c.1079A>C p.N360T | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV99231940; called by muse, mutect2, varscan2
- ICE1 | c.6235G>A p.D2079N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV99664517; called by muse, mutect2, varscan2
- IFNA13 | c.435G>C p.K145N | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV101489481; called by muse, mutect2, varscan2
- ILF2 | c.1010G>A p.S337N | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs1221585865, COSV100721927; called by muse, mutect2, varscan2
- INPP5J | c.2074G>T p.G692C (on ENST00000331075 / NM_001284285.2; = p.G324C on NM_001002837.2) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100459384; called by muse, mutect2, varscan2
- INSIG2 | c.44G>C p.G15A | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV99830490, COSV99830510; called by muse, mutect2, varscan2
- INTS3 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 60/369 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100015906; called by muse, mutect2, varscan2
- IRS4 | c.3578C>G p.S1193C | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.257); catalogued as COSV100929529; called by muse, mutect2, varscan2
- KCNB2 | c.371A>G p.D124G | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101578750; called by muse, mutect2, varscan2
- KCNH1 | c.437A>C p.K146T | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.754); catalogued as COSV99658756; called by muse, mutect2, varscan2
- KCNH1 | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV55105021; called by muse, mutect2, varscan2
- KIF7 | c.2878C>T p.R960C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs766652877, COSV99176328; called by muse, mutect2, varscan2
- KLHDC4 | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as COSV99566357; called by muse, mutect2, varscan2
- KMT2A | c.10184A>T p.Q3395L | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.397); catalogued as COSV100628598; called by muse, mutect2, varscan2
- KNDC1 | c.5132G>T p.G1711V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV100464457; called by muse, mutect2, varscan2
- KRT7 | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.436); catalogued as rs373120760; called by muse, mutect2
- KRT82 | c.522C>A p.S174R | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.058); catalogued as rs146028432; called by muse, mutect2
- KRTAP10-11 | c.53A>T p.Q18L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV100553150; called by muse, mutect2, varscan2
- KTN1 | c.3214G>T p.A1072S (on ENST00000395314 / NM_001271014.2; = p.A1043S on NM_004986.4) | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV100618323; called by muse, mutect2, varscan2
- LDB1 | c.760G>C p.E254Q (on ENST00000425280 / NM_001321612.2; = p.E218Q on NM_003893.5) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100756379; called by muse, mutect2, varscan2
- LRP2 | c.10053G>A p.M3351I | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99787998; called by muse, mutect2, varscan2
- LRP2 | c.1903C>A p.P635T | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV99788000; called by muse, mutect2, varscan2
- LRRC30 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV101274398; called by muse, mutect2, varscan2
- LRRC49 | c.146del p.G49Vfs*23 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as COSV51436142; called by mutect2, pindel, varscan2
- LRRC4B | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100975894, COSV65350745; called by muse, mutect2, varscan2
- LSS | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903364744, COSV62701118; called by muse, mutect2
- MARCO | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1189317036, COSV100503394; called by muse, mutect2, varscan2
- MASTL | c.2468G>C p.R823T (on ENST00000375940 / NM_001372029.1; = p.R822T on NM_032844.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751976926, COSV100668874; called by muse, mutect2, varscan2
- MATK | c.1195G>T p.G399W (on ENST00000310132 / NM_139355.3; = p.G400W on NM_002378.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV100035821; called by muse, mutect2, varscan2
- MATN2 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV99646153; called by muse, mutect2, varscan2
- MDH1B | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99378922; called by muse, mutect2, varscan2
- MN1 | c.2948G>T p.G983V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV100179806; called by muse, mutect2
- MORC1 | c.351T>A p.F117L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV99225872; called by muse, mutect2, varscan2
- MS4A14 | c.1205C>G p.S402C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.712); catalogued as COSV100280323, COSV55738025; called by muse, mutect2, varscan2
- MSH2 | c.709A>T p.I237F | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV51885567, COSV99253720; called by muse, mutect2, varscan2
- MSI1 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99981492; called by muse, mutect2, varscan2
- MTMR1 | c.261G>T p.R87S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.717); catalogued as COSV100953912; called by muse, mutect2
- MUC16 | c.34661G>A p.G11554E | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.158); catalogued as COSV101199557; called by muse, mutect2, varscan2
- MYBPC1 | c.2748C>A p.D916E (on ENST00000550270 / NM_206820.2; = p.D923E on NM_002465.4) | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100637931; called by muse, mutect2, varscan2
- MYH11 | c.4083C>A p.N1361K | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.232); catalogued as COSV100258669; called by muse, mutect2, varscan2
- MYO3A | c.16G>T p.G6* | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | catalogued as COSV99779401; called by muse, mutect2, varscan2
- MYOM3 | c.3514G>A p.G1172R | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.725); catalogued as COSV100141672; called by muse, mutect2, varscan2
- MYT1L | c.2010del p.G672Dfs*30 | Frame Shift Del (DEL) | VAF 11/91 reads (12%) | catalogued as COSV67710165, COSV67731728; called by mutect2, pindel, varscan2
- NAE1 | c.901-1G>T p.X301_splice | Splice Site (SNP) | VAF 22/103 reads (21%) | catalogued as COSV99323073; called by muse, mutect2, varscan2
- NANOG | c.109T>A p.S37T | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV99981532; called by muse, mutect2, varscan2
- NCOA6 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV100749969; called by muse, varscan2
- NDST4 | c.1946T>C p.M649T | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99996236, COSV99998075; called by muse, mutect2, varscan2
- NDUFAF7 | c.843C>G p.I281M | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.515); catalogued as COSV99135513; called by muse, mutect2, varscan2
- NDUFB5 | c.195G>T p.R65S | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV99372534; called by muse, mutect2, varscan2
- NEDD1 | c.1812A>T p.R604S | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99900952; called by muse, mutect2, varscan2
- NFE2L3 | c.1847A>G p.K616R | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV99283650; called by muse, mutect2, varscan2
- NFXL1 | c.1745G>T p.C582F | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100216742; called by muse, mutect2, varscan2
- NLRP13 | c.2975T>A p.L992Q | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100738187; called by muse, mutect2, varscan2
- NLRP7 | c.2286C>A p.N762K (on ENST00000340844 / NM_206828.3; = p.N734K on NM_139176.3) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.168); catalogued as COSV100052385; called by muse, mutect2
- NLRX1 | c.1352G>T p.G451V | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as COSV99424131; called by muse, mutect2, varscan2
- NRP2 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 101/519 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99784187; called by muse, mutect2, varscan2
- NUCB2 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.287); catalogued as rs767528199, COSV100082705; called by muse, mutect2, varscan2
- NUP153 | c.1159C>G p.L387V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100020178, COSV100020900; called by muse, mutect2, varscan2
- NYAP2 | c.1272G>T p.Q424H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.621); catalogued as COSV99796397; called by muse, mutect2
- OBP2B | c.277+1G>T p.X93_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100922847; called by muse, mutect2
- OBSCN | c.2537A>G p.Q846R | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99476803; called by muse, mutect2, varscan2
- OR10A4 | c.95T>C p.F32S | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV101139500; called by muse, mutect2, varscan2
- OR10A4 | c.919C>G p.H307D | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV101139502; called by muse, mutect2, varscan2
- OR2G6 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV58574098; called by muse, mutect2, varscan2
- OR2T11 | c.573G>T p.L191F | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV100424790; called by muse, mutect2, varscan2
- OR2T3 | c.835G>C p.V279L | Missense Mutation (SNP) | VAF 33/436 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); catalogued as COSV100613196, COSV62081711; called by muse, mutect2
- OR2T34 | c.835G>C p.V279L | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV100170356; called by muse, mutect2, varscan2
- OR2T4 | c.701G>A p.C234Y | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100822466; called by muse, mutect2, varscan2
- OR5B3 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.303); catalogued as COSV58678360; called by muse, mutect2, varscan2
- OR5B3 | c.120C>A p.N40K | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs751580052, COSV58677021, COSV58678783; called by muse, mutect2, varscan2
- OR5M3 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV100392471; called by muse, mutect2, varscan2
- OR5M3 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV56566043, COSV56567278; called by muse, mutect2, varscan2
- OR6C65 | c.510C>A p.S170R | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.376); catalogued as COSV101110183; called by muse, mutect2, varscan2
- OR7D4 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.139); catalogued as COSV100432700; called by muse, mutect2, varscan2
- OR8K5 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.083); catalogued as COSV100537202; called by muse, mutect2, varscan2
- OR9K2 | c.929C>A p.P310H (on ENST00000305377; = p.P288H on NM_001005243.1) | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59533333; called by muse, mutect2, varscan2
- ORC5 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 19/101 reads (19%) | catalogued as COSV99856932; called by muse, mutect2, varscan2
- OTOF | c.2038G>T p.G680W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV99717414; called by muse, mutect2
- OTOGL | c.2533G>C p.E845Q (on ENST00000547103; = p.E836Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.532); catalogued as COSV101509186; called by muse, mutect2
- OTUD7A | c.1977G>C p.E659D (on ENST00000307050 / NM_001382637.1; = p.E652D on NM_130901.3) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100192342; called by muse, mutect2
- OTUD7B | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64917502; called by muse, mutect2, varscan2
- OTULINL | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.183); catalogued as rs1237840845, COSV99947132; called by muse, mutect2, varscan2
- PAPPA2 | c.3005T>C p.F1002S | Missense Mutation (SNP) | VAF 59/288 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs956036639, COSV100867909; called by muse, mutect2, varscan2
- PARD3 | c.3716C>A p.S1239Y | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100631772, COSV61053359; called by muse, mutect2, varscan2
- PAXBP1 | c.1549G>T p.D517Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs778420280, COSV51608442, COSV51611603; called by muse, mutect2, varscan2
- PCDH12 | c.2764C>A p.P922T | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV99187607; called by muse, mutect2, varscan2
- PCDHA2 | c.1072C>G p.P358A | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV100973801, COSV65366979; called by muse, mutect2, varscan2
- PCDHB4 | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.811); catalogued as COSV52025275; called by muse, mutect2, varscan2
- PDE11A | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV99611864; called by muse, mutect2, varscan2
- PDGFD | c.650T>A p.F217Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV100158854; called by muse, mutect2
- PDILT | c.1277T>C p.L426P | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100199318; called by muse, mutect2, varscan2
- PEG3 | c.3275C>A p.S1092* | Nonsense Mutation (SNP) | VAF 20/129 reads (16%) | catalogued as COSV99688599; called by muse, mutect2, varscan2
- PHKG1 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99818169; called by muse, mutect2
- PI16 | c.402G>A p.W134* | Nonsense Mutation (SNP) | VAF 20/143 reads (14%) | catalogued as rs1371235966, COSV101028670; called by muse, mutect2, varscan2
- PIK3AP1 | c.673A>T p.K225* | Nonsense Mutation (SNP) | VAF 17/119 reads (14%) | catalogued as COSV100225714; called by muse, mutect2, varscan2
- PIP | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV99344127; called by muse, varscan2
- PLD5 | c.709G>C p.G237R (on ENST00000442594; = p.G175R on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV100139194, COSV100139984, COSV59156719; called by mutect2, varscan2
- PLEKHG2 | c.262C>A p.H88N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.112); catalogued as COSV99217285; called by muse, mutect2
- PLXNA3 | c.2404C>T p.R802C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs957481889, COSV100859920, COSV63755931; called by muse, mutect2, varscan2
- POTEF | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 13/129 reads (10%) | catalogued as COSV100664834; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1889C>A p.A630E | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV53452241, COSV99461195; called by muse, mutect2, varscan2
- PPIP5K1 | c.3754G>T p.E1252* (on ENST00000396923; = p.E1227* on NM_014659.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/189 reads (16%) | catalogued as COSV100288544; called by muse, mutect2, varscan2
- PPM1A | c.667G>C p.D223H | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100349000; called by muse, mutect2, varscan2
- PPP4R1 | c.2611C>G p.L871V (on ENST00000400556 / NM_001042388.3; = p.L854V on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV99553400; called by muse, mutect2, varscan2
- PRDM9 | c.885C>G p.I295M | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57007968, COSV99690319; called by muse, mutect2, varscan2
- PRICKLE2 | c.2459G>T p.R820L (on ENST00000295902; = p.R764L on NM_198859.4) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as rs546936479, COSV55768782, COSV99897096; called by muse, mutect2, varscan2
- PRKD1 | c.2521-1G>T p.X841_splice | Splice Site (SNP) | VAF 14/84 reads (17%) | catalogued as COSV100120023; called by muse, mutect2, varscan2
- PRMT5 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 56/325 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV99362930; called by muse, mutect2, varscan2
- PROM2 | c.2255G>T p.R752L | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.545); catalogued as COSV100468909; called by muse, mutect2, varscan2
- PRPF40A | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100582781; called by muse, mutect2, varscan2
- PRTG | c.2288G>A p.G763D | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101221359; called by muse, mutect2, varscan2
- PSMD2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV100031698; called by muse, mutect2, varscan2
- PTGER3 | c.1152T>A p.H384Q | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV100656798; called by muse, varscan2
- PTPRO | c.2201A>G p.K734R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.721); catalogued as COSV99840346; called by muse, varscan2
- PTPRZ1 | c.1967G>C p.S656T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as COSV101099985; called by muse, mutect2, varscan2
- PURG | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV53297054, COSV99988875; called by muse, mutect2, varscan2
- PWWP2A | c.1342A>G p.T448A | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs543966066, COSV100193822; called by muse, mutect2, varscan2
- RAB10 | c.318C>G p.N106K | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV99265932; called by muse, mutect2, varscan2
- RAD50 | c.1577A>T p.E526V | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as COSV99528881; called by muse, mutect2, varscan2
- RBM27 | c.2136G>T p.Q712H | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as COSV99506052; called by muse, mutect2, varscan2
- RGS18 | c.701G>C p.W234S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100817752; called by mutect2, varscan2
- RHOH | c.140T>C p.M47T | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV101110474; called by muse, mutect2, varscan2
- RIOK3 | c.1009G>T p.A337S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs199977739, COSV100259283, COSV100259362; called by muse, mutect2
- ROBO3 | c.3976T>A p.Y1326N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); catalogued as COSV100127517; called by muse, mutect2, varscan2
- ROBO4 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as rs1340806291, COSV100127519; called by muse, mutect2, varscan2
- RPL8 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs376660224; called by muse, mutect2, varscan2
- RRP12 | c.1282C>G p.H428D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV100213115; called by muse, mutect2
- RTN1 | c.2210T>A p.V737E | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99955400; called by muse, mutect2, varscan2
- RTN1 | c.1083A>T p.K361N | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV99955402; called by muse, mutect2
- RTTN | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.725); catalogued as rs368406992, COSV99732041; called by muse, mutect2, varscan2
- RYR2 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV100769684; called by muse, mutect2, varscan2
- SACS | c.5646G>T p.L1882F | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101207392; called by muse, mutect2, varscan2
- SBSN | c.376G>T p.V126F (on ENST00000452271 / NM_001166034.2; = p.X125_splice on NM_198538.4) | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV101510065; called by muse, mutect2, varscan2
- SCG2 | c.119C>G p.P40R | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs757584964, COSV100544697; called by muse, mutect2, varscan2
- SCML4 | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100940265; called by muse, mutect2
- SCN2A | c.4147T>C p.Y1383H | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99331266; called by muse, mutect2, varscan2
- SDK2 | c.3791C>A p.T1264N | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as COSV101167418; called by muse, mutect2, varscan2
- SELENBP1 | c.457G>T p.G153* | Nonsense Mutation (SNP) | VAF 46/281 reads (16%) | catalogued as COSV100923556; called by muse, mutect2, varscan2
- SFPQ | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100599401; called by muse, mutect2, varscan2
- SHANK1 | c.653C>A p.T218K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99520972; called by muse, mutect2, varscan2
- SI | c.4713G>T p.W1571C | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100015213; called by muse, mutect2, varscan2
- SI | c.3565G>T p.G1189* | Nonsense Mutation (SNP) | VAF 32/107 reads (30%) | catalogued as COSV100013725; called by muse, mutect2, varscan2
- SIRT1 | c.789G>T p.G263= | Splice Region (SNP) | VAF 13/121 reads (11%) | catalogued as COSV99281737; called by muse, mutect2, varscan2
- SIRT1 | c.789+1G>T p.X263_splice | Splice Site (SNP) | VAF 14/121 reads (12%) | catalogued as COSV99281739; called by muse, mutect2, varscan2
- SLC13A5 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV99545850, COSV99545857; called by muse, mutect2, varscan2
- SLC22A15 | c.587G>T p.W196L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV101047243; called by muse, mutect2, varscan2
- SLC22A4 | c.1331T>A p.L444Q | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99569286; called by muse, mutect2, varscan2
- SLC24A4 | c.1853G>A p.C618Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100104979; called by muse, mutect2, varscan2
- SLC24A5 | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99981491; called by muse, mutect2, varscan2
- SLC39A8 | c.1324A>G p.T442A | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs748146004, COSV100765699; called by muse, mutect2, varscan2
- SLC44A5 | c.1976G>T p.G659V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1469685280, COSV100901837; called by muse, mutect2
- SLC5A9 | c.1352C>A p.S451Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99361589; called by muse, mutect2, varscan2
- SLC6A7 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 29/132 reads (22%) | catalogued as COSV100046234; called by muse, mutect2, varscan2
- SLCO4A1 | c.1559G>T p.G520V | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV99414680; called by muse, mutect2, varscan2
- SNRPN | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV100578146; called by muse, mutect2, varscan2
- SNTG2 | c.977C>A p.P326Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as COSV58002139; called by muse, mutect2, varscan2
- SOX5 | c.1556G>T p.S519I | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.147); catalogued as COSV100506654; called by muse, mutect2, varscan2
- SP1 | c.639G>C p.Q213H (on ENST00000327443 / NM_138473.3; = p.Q206H on NM_003109.1) | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV100540536, COSV100540951; called by muse, mutect2, varscan2
- SPHKAP | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1264268232, COSV100764068; called by muse, mutect2, varscan2
- SPTA1 | c.715C>A p.Q239K | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as COSV100934776; called by muse, mutect2, varscan2
- STAB1 | c.7595C>T p.P2532L | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1301592467, COSV100194830; called by muse, mutect2, varscan2
- SYNE2 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV58359048; called by muse, mutect2, varscan2
- SYNE2 | c.1040T>C p.L347S | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV100647439; called by muse, mutect2, varscan2
- SYT9 | c.626A>G p.D209G | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV100607989; called by muse, mutect2, varscan2
- TAF1L | c.811G>C p.V271L | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99644174, COSV99644536; called by muse, mutect2, varscan2
- TCTN2 | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.175); catalogued as COSV100315187; called by muse, mutect2, varscan2
- TCTN2 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.241); catalogued as COSV100315188; called by muse, mutect2, varscan2
- TECPR1 | c.476G>C p.R159P | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762666517, COSV101130434; called by mutect2, varscan2
- TEP1 | c.3711A>T p.R1237= | Splice Region (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99402189; called by muse, mutect2
- TFAP2A | c.770G>A p.R257K (on ENST00000482890; = p.R249K on NM_001032280.3) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV100116793; called by muse, mutect2
- THAP12 | c.859C>G p.H287D | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99472910; called by muse, mutect2, varscan2
- TKTL2 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.119); catalogued as rs765173088, COSV54917868; called by muse, mutect2, varscan2
- TLN2 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV100168792; called by muse, mutect2, varscan2
- TLR7 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1225846451, COSV101027838; called by muse, mutect2, varscan2
- TMC3 | c.1645T>A p.F549I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100845894, COSV63922124, COSV63923281; called by muse, mutect2, varscan2
- TMED8 | c.578T>C p.I193T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV99374918; called by muse, mutect2, varscan2
- TMPRSS9 | c.3270C>G p.H1090Q (on ENST00000648592; = p.H1056Q on NM_182973.2) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as COSV99295948; called by muse, mutect2, varscan2
- TRIM24 | c.1019T>A p.M340K | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100630891; called by muse, mutect2, varscan2
- TRIM27 | c.1349A>G p.Y450C | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101019299; called by muse, mutect2, varscan2
- TRIM51 | c.1296C>A p.Y432* | Nonsense Mutation (SNP) | VAF 32/187 reads (17%) | catalogued as COSV99792485; called by muse, varscan2
- TRIM51 | c.1324C>A p.P442T | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99792489; called by muse, varscan2
- TRIP11 | c.1624A>G p.R542G | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as COSV99970597; called by muse, mutect2, varscan2
- TRPC4AP | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs541626179, COSV99328262; called by muse, mutect2, varscan2
- TRPM4 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.617); catalogued as rs865856899, COSV99419610; called by muse, mutect2, varscan2
- TSEN34 | c.259A>C p.K87Q | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99824774; called by muse, mutect2, varscan2
- TSHZ3 | c.2776G>C p.D926H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53668064, COSV99551324; called by muse, mutect2, varscan2
- TSPAN16 | c.264G>C p.L88F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100368324; called by muse, mutect2
- TTC37 | c.2357A>G p.Y786C | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100706573; called by muse, mutect2, varscan2
- TTLL6 | c.1263G>T p.L421F (on ENST00000393382 / NM_001130918.3; = p.L114F on NM_173623.3) | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100938100; called by muse, mutect2, varscan2
- TTN | c.6275G>A p.G2092E (on ENST00000591111; = p.G2046E on NM_003319.4) | Missense Mutation (SNP) | VAF 19/107 reads (18%) | PolyPhen possibly damaging (0.714); catalogued as COSV59887856; called by muse, mutect2, varscan2
- U2AF2 | c.569A>T p.Q190L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58272812; called by muse, mutect2, varscan2
- UACA | c.2374T>A p.L792I | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100537470; called by muse, mutect2, varscan2
- UBR2 | c.3243-1G>T p.X1081_splice | Splice Site (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100867418; called by muse, mutect2
- UGGT2 | c.3642A>T p.K1214N | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV100948638; called by muse, mutect2, varscan2
- UGT3A2 | c.722T>C p.L241P | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV99236255; called by muse, mutect2, varscan2
- UGT3A2 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs1219050309, COSV99236256; called by muse, mutect2, varscan2
- UNC5D | c.1771C>T p.Q591* | Nonsense Mutation (SNP) | VAF 26/105 reads (25%) | catalogued as COSV99774533; called by muse, mutect2, varscan2
- UNC79 | c.2031C>A p.Y677* (on ENST00000393151 / NM_001346218.2; = p.Y500* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 39/219 reads (18%) | catalogued as COSV99827413; called by muse, mutect2, varscan2
- UNC79 | c.3478G>T p.A1160S (on ENST00000393151 / NM_001346218.2; = p.A983S on NM_020818.5) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as COSV99827420; called by muse, mutect2, varscan2
- USP13 | c.284A>T p.H95L | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1200897287, COSV99831062; called by muse, mutect2, varscan2
- USP21 | c.900G>T p.Q300H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57090400, COSV99237351; called by muse, mutect2, varscan2
- USP29 | c.620G>T p.R207M | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as rs754130044, COSV99518009; called by muse, mutect2, varscan2
- USP51 | c.565_566insT p.G189Vfs*14 | Frame Shift Ins (INS) | VAF 7/15 reads (47%) | catalogued as COSV101540659; called by mutect2, varscan2
- VWA3B | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as rs1431107021, COSV101346014; called by muse, mutect2
- VWA5A | c.1863G>T p.K621N | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV100827843; called by muse, mutect2, varscan2
- WASHC2C | c.1257T>A p.F419L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as COSV100313941; called by muse, mutect2, varscan2
- WDFY3 | c.8684G>T p.R2895L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99883149; called by muse, mutect2, varscan2
- WT1 | c.888T>C p.S296= | Splice Region (SNP) | VAF 22/87 reads (25%) | catalogued as COSV100187892; called by muse, mutect2, varscan2
- WWC1 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs369308732; called by muse, mutect2, varscan2
- ZBTB46 | c.134A>C p.H45P | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99829063; called by muse, mutect2, varscan2
- ZEB1 | c.1097G>C p.C366S | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.36); catalogued as rs754854286, COSV100314223; called by muse, mutect2, varscan2
- ZMIZ2 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.097); catalogued as COSV99536804; called by muse, mutect2, varscan2
- ZNF112 | c.641G>T p.S214I (on ENST00000337401 / NM_001083335.2; = p.S208I on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV100495709; called by muse, mutect2, varscan2
- ZNF384 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.214); catalogued as COSV100158418; called by muse, mutect2, varscan2
- ZNF418 | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as COSV101268920; called by muse, mutect2, varscan2
- ZNF500 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 20/107 reads (19%) | catalogued as COSV99556278; called by muse, mutect2, varscan2
- ZNF532 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV100266385; called by muse, mutect2, varscan2
- ZNF594 | c.552A>G p.I184M | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs867719990, COSV101280475; called by muse, mutect2, varscan2
- ZNF606 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs377426318; called by muse, mutect2, varscan2
- ZNF626 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV74129061, COSV99081904; called by muse, mutect2, varscan2
- ZNF680 | c.377G>T p.C126F | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV100549103; called by muse, mutect2, varscan2
- ZNF682 | c.1484A>G p.N495S | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100653248; called by muse, mutect2, varscan2
- ZNF714 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99395177; called by muse, mutect2, varscan2
- ZNF75D | c.59G>T p.W20L | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100883627; called by muse, mutect2, varscan2
- ZNF773 | c.578G>T p.C193F | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99989229; called by muse, mutect2, varscan2
- ACACB | c.4909del p.R1637Afs*31 | Frame Shift Del (DEL) | VAF 49/314 reads (16%) | called by mutect2, pindel, varscan2
- DHRS4 | c.412_413del p.L138Gfs*3 | Frame Shift Del (DEL) | VAF 15/94 reads (16%) | called by pindel, varscan2
- FGA | c.2009del p.G670Efs*5 | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | called by mutect2, pindel, varscan2
- FTO | c.1506del p.A503Qfs*50 | Frame Shift Del (DEL) | VAF 38/261 reads (15%) | called by mutect2, pindel, varscan2
- GTPBP10 | c.465-1G>T p.X155_splice | Splice Site (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- HMCN1 | c.16237_16240del p.R5413Lfs*18 | Frame Shift Del (DEL) | VAF 38/224 reads (17%) | called by mutect2, pindel*, varscan2*
- IGHG4 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 42/604 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.551); called by muse, mutect2
- IGKV1D-8 | c.322T>G p.Y108D | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KYNU | c.918del p.F306Lfs*17 | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | called by mutect2, pindel, varscan2
- MEX3A | c.1084dup p.D362Gfs*27 | Frame Shift Ins (INS) | VAF 14/83 reads (17%) | called by mutect2, pindel, varscan2
- PABPC3 | c.1006G>C p.G336R | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB9 | c.620A>T p.E207V | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PRAMEF17 | c.1376C>G p.S459C | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRAV30 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TSC1 | c.2831_2840del p.A944Gfs*8 | Frame Shift Del (DEL) | VAF 23/152 reads (15%) | called by mutect2, pindel, varscan2
- VN1R5 | c.500T>A p.F167Y | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZNF26 | c.626G>T p.R209I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZRANB3 | c.43_73del p.I15Cfs*9 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel
- ABCA9 | c.2724A>G p.Q908= | Silent (SNP) | VAF 79/441 reads (18%) | catalogued as rs565590195, COSV100383025; called by muse, mutect2, varscan2
- ALOX5AP | c.234C>T p.C78= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100996278; called by muse, mutect2, varscan2
- ALPP | c.459C>A p.S153= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV101235135; called by muse, mutect2, varscan2
- ANO3 | c.1683G>T p.V561= | Silent (SNP) | VAF 36/217 reads (17%) | catalogued as COSV99882299; called by muse, mutect2, varscan2
- APOB | c.3126G>A p.A1042= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs547789079, COSV51921607; ClinVar: likely benign; called by muse, mutect2, varscan2
- ASTN2 | c.1812G>A p.P604= (on ENST00000313400 / NM_001365069.1; = p.P553= on NM_014010.5) | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs773572727, COSV57787097; called by muse, mutect2, varscan2
- BLK | c.894A>T p.R298= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99377120; called by muse, mutect2
- C10orf71 | c.321G>A p.Q107= | Silent (SNP) | VAF 19/155 reads (12%) | catalogued as COSV100110056; called by muse, mutect2, varscan2
- CARD6 | c.2280G>A p.E760= | Silent (SNP) | VAF 69/377 reads (18%) | catalogued as COSV99620687; called by muse, mutect2, varscan2
- CBL | c.2493C>T p.I831= | Silent (SNP) | VAF 38/212 reads (18%) | catalogued as rs1165091755, COSV99876132; called by muse, mutect2, varscan2
- CCDC134 | c.291G>A p.Q97= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99740661; called by muse, mutect2
- CD163 | c.1770C>A p.T590= | Silent (SNP) | VAF 28/174 reads (16%) | catalogued as COSV100775565, COSV63129717; called by muse, mutect2, varscan2
- CHD7 | c.7245C>G p.A2415= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV101418194; called by muse, mutect2, varscan2
- CNR1 | c.1389G>T p.V463= | Silent (SNP) | VAF 62/328 reads (19%) | catalogued as COSV100759207, COSV62986447; called by muse, mutect2, varscan2
- COPG1 | c.2568G>T p.V856= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as COSV100135555; called by muse, mutect2, varscan2
- CRACD | c.3606C>T p.T1202= | Silent (SNP) | VAF 38/266 reads (14%) | catalogued as rs1167129583, COSV99949120; called by muse, mutect2, varscan2
- CREG2 | c.486C>T p.G162= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV100240421; called by muse, mutect2, varscan2
- CRYBG3 | c.8799T>C p.S2933= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV99476912; called by muse, mutect2, varscan2
- CTNND2 | c.3162C>A p.S1054= | Silent (SNP) | VAF 91/196 reads (46%) | catalogued as COSV100475538; called by muse, mutect2, varscan2
- CUL7 | c.2317C>A p.R773= | Silent (SNP) | VAF 33/153 reads (22%) | catalogued as COSV99538432; called by muse, mutect2, varscan2
- CYP4F12 | c.1479A>T p.P493= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100215790; called by muse, mutect2, varscan2
- DAAM2 | c.1854C>T p.V618= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as rs1228307595; called by muse, mutect2
- DES | c.1412A>G p.*471= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV100900394; called by muse, mutect2, varscan2
- DLGAP3 | c.1056G>T p.G352= | Silent (SNP) | VAF 27/133 reads (20%) | catalogued as rs372415552, COSV99332531; called by muse, mutect2, varscan2
- DOP1B | c.3933C>G p.L1311= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV101215280; called by muse, mutect2, varscan2
- DSP | c.807G>T p.L269= | Silent (SNP) | VAF 35/154 reads (23%) | catalogued as COSV101131247, COSV65793463; called by muse, mutect2, varscan2
- DUSP21 | c.63C>T p.S21= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100173557; called by muse, mutect2, varscan2
- EIF3A | c.1701G>T p.R567= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100974581; called by muse, mutect2, varscan2
- FCHO1 | c.321C>G p.L107= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99406055, COSV99406097; called by muse, varscan2
- FNDC1 | c.3771C>A p.V1257= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99795613; called by muse, varscan2
- FREM2 | c.6660C>A p.G2220= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV99748426; called by muse, mutect2, varscan2
- FRS2 | c.379T>C p.L127= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs541934715, COSV100165878; called by muse, mutect2, varscan2
- GABBR2 | c.747G>T p.R249= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV99409803; called by muse, mutect2
- GLRA4 | c.1242C>A p.L414= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100129017, COSV60327661; called by muse, mutect2, varscan2
- GPR158 | c.837C>T p.P279= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs1410310054, COSV100893367; called by muse, mutect2, varscan2
- HAS1 | c.675G>T p.A225= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99708351; called by muse, mutect2, varscan2
- HEY1 | c.207G>A p.L69= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV100559212; called by muse, mutect2, varscan2
- HNRNPU | c.1377A>T p.A459= (on ENST00000283179; = p.A521= on NM_004501.3) | Silent (SNP) | VAF 32/235 reads (14%) | catalogued as COSV51694808; called by muse, mutect2, varscan2
- HSF4 | c.588T>G p.L196= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV99263490; called by muse, varscan2
- IGF1R | c.2640G>T p.V880= | Silent (SNP) | VAF 31/293 reads (11%) | catalogued as COSV99151180; called by muse, mutect2, varscan2
- IGKV1D-17 | c.267T>A p.S89= | Silent (SNP) | VAF 37/254 reads (15%) | called by muse, mutect2, varscan2
- INTS7 | c.2493A>T p.V831= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as COSV100877477; called by muse, mutect2, varscan2
- ITPR2 | c.4656A>C p.P1552= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV101189947; called by muse, mutect2
- KDM8 | c.624G>A p.L208= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99619190, COSV99619511; called by muse, mutect2, varscan2
- KHDRBS2 | c.1008A>T p.S336= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV99833052; called by muse, mutect2, varscan2
- KLHDC4 | c.1236G>T p.R412= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV54510036; called by muse, mutect2, varscan2
- KLRB1 | c.597T>A p.S199= | Silent (SNP) | VAF 18/137 reads (13%) | catalogued as COSV99987237; called by muse, mutect2, varscan2
- KRTAP10-11 | c.54G>A p.Q18= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV100553154; called by muse, mutect2, varscan2
- LCP1 | c.1269C>T p.A423= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as rs1228886003; called by muse, mutect2
- LHFPL2 | c.60G>T p.V20= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100982511; called by muse, mutect2, varscan2
- LRRK2 | c.381C>T p.A127= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100109952; called by muse, mutect2, varscan2
- MAGI2 | c.1860C>A p.A620= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100834217; called by muse, mutect2, varscan2
- MARCHF1 | c.375C>A p.L125= (on ENST00000274056; = p.L108= on NM_017923.4) | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV99920715; called by muse, mutect2, varscan2
- MASTL | c.1833A>G p.T611= | Silent (SNP) | VAF 52/151 reads (34%) | catalogued as COSV100668873; called by muse, mutect2, varscan2
- MCCD1 | c.84C>A p.S28= | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as COSV100871057; called by muse, mutect2, varscan2
- MYH1 | c.4995C>G p.L1665= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV99875674; called by muse, mutect2, varscan2
- MYH11 | c.2325G>T p.L775= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100258674; called by muse, mutect2, varscan2
- MYH2 | c.5359C>A p.R1787= | Silent (SNP) | VAF 23/153 reads (15%) | catalogued as rs140762786, COSV55432543, COSV55449201; called by muse, mutect2, varscan2
- MYO1F | c.2250C>A p.P750= | Silent (SNP) | VAF 57/363 reads (16%) | catalogued as COSV57798627; called by muse, mutect2, varscan2
- MYOCD | c.2760G>T p.L920= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100590640; called by muse, mutect2, varscan2
- NAV1 | c.810G>A p.Q270= | Silent (SNP) | VAF 33/210 reads (16%) | catalogued as COSV99818671; called by muse, mutect2, varscan2
- NKAIN3 | c.258A>T p.V86= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100133224; called by muse, mutect2
- NLRP4 | c.2340C>A p.V780= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV100016171; called by muse, mutect2, varscan2
- NOS3 | c.2598C>A p.T866= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV99871556; called by muse, mutect2, varscan2
- NYAP2 | c.369G>T p.S123= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV99796394; called by muse, mutect2, varscan2
- OR13C2 | c.921A>G p.V307= | Silent (SNP) | VAF 46/233 reads (20%) | catalogued as COSV101604868, COSV73377719; called by muse, mutect2, varscan2
- OR13C4 | c.135G>C p.L45= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as COSV99470129; called by muse, mutect2, varscan2
- OR2A7 | c.96G>C p.L32= | Silent (SNP) | VAF 13/230 reads (6%) | called by muse, mutect2
- OR2G3 | c.141C>A p.I47= | Silent (SNP) | VAF 33/332 reads (10%) | catalogued as COSV60681988, COSV60682501; called by muse, mutect2
- OR2T34 | c.600T>C p.Y200= | Silent (SNP) | VAF 81/272 reads (30%) | catalogued as rs1467428129, COSV100170357; called by muse, mutect2, varscan2
- OR4M1 | c.558G>T p.R186= | Silent (SNP) | VAF 36/528 reads (7%) | catalogued as COSV100271148, COSV60059920, COSV60061852; called by muse, mutect2
- OR5I1 | c.27G>T p.T9= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100041374; called by muse, mutect2, varscan2
- OR5R1 | c.321C>T p.F107= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV56573855; called by muse, mutect2, varscan2
- PAPPA2 | c.4053C>G p.G1351= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV100867910; called by muse, mutect2, varscan2
- PARP12 | c.1539C>G p.V513= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV99694005; called by muse, mutect2, varscan2
- PDZRN3 | c.2877C>T p.T959= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs1402008215, COSV55208779; called by muse, mutect2, varscan2
- PHGDH | c.1269G>T p.L423= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV101025088; called by muse, mutect2, varscan2
- PLPP2 | c.432G>T p.V144= | Silent (SNP) | VAF 30/178 reads (17%) | catalogued as COSV99514633; called by muse, mutect2, varscan2
- POTEE | c.1953G>A p.L651= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100387699; called by mutect2, varscan2
- PPP2R1B | c.1737A>G p.L579= | Silent (SNP) | VAF 22/153 reads (14%) | catalogued as COSV100232102; called by muse, mutect2, varscan2
- PRUNE2 | c.6699T>C p.T2233= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV100944482; called by muse, mutect2, varscan2
- PTCH2 | c.84G>C p.G28= | Silent (SNP) | VAF 16/147 reads (11%) | catalogued as COSV100942090, COSV100942311; called by muse, mutect2, varscan2
- QRICH1 | c.714G>T p.T238= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100676764; called by muse, mutect2, varscan2
- RHBG | c.84C>A p.V28= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99659492; called by muse, mutect2, varscan2
- RIMBP2 | c.2019C>A p.A673= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99899251; called by muse, mutect2
- RSPRY1 | c.588T>A p.P196= | Silent (SNP) | VAF 40/250 reads (16%) | catalogued as COSV101070989; called by muse, mutect2, varscan2
- RYR1 | c.7356G>C p.R2452= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100615486, COSV62101821; called by muse, mutect2, varscan2
- SAMD9 | c.2487G>C p.L829= | Silent (SNP) | VAF 25/162 reads (15%) | catalogued as COSV101180204; called by muse, mutect2, varscan2
- SI | c.4332T>C p.L1444= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV100015216; called by muse, mutect2, varscan2
- SIGLEC5 | c.1614C>A p.A538= | Silent (SNP) | VAF 23/161 reads (14%) | catalogued as COSV55777744, COSV99707433; called by muse, mutect2, varscan2
- SLC17A1 | c.1284C>G p.A428= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV99765719; called by muse, mutect2, varscan2
- SLC39A8 | c.489C>T p.T163= | Silent (SNP) | VAF 56/279 reads (20%) | catalogued as COSV100765701; called by muse, mutect2, varscan2
- SLC6A7 | c.603C>T p.I201= | Silent (SNP) | VAF 28/131 reads (21%) | catalogued as COSV100046231; called by muse, mutect2, varscan2
- SNX25 | c.138G>T p.L46= | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as COSV99252731; called by muse, mutect2, varscan2
- SPG7 | c.1041G>A p.G347= (on ENST00000268704; = p.G354= on NM_003119.4) | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99244837; called by muse, mutect2, varscan2
- STAM2 | c.429T>C p.F143= | Silent (SNP) | VAF 23/153 reads (15%) | catalogued as COSV99812994; called by muse, mutect2, varscan2
- SYT14 | c.1464C>T p.V488= | Silent (SNP) | VAF 26/170 reads (15%) | catalogued as COSV55050858, COSV99655051; called by muse, mutect2, varscan2
- TBX5 | c.573T>C p.N191= | Silent (SNP) | VAF 55/353 reads (16%) | catalogued as COSV100091089; called by muse, mutect2, varscan2
- TET1 | c.5985A>C p.S1995= | Silent (SNP) | VAF 34/180 reads (19%) | catalogued as COSV101018066; called by muse, mutect2, varscan2
- THAP12 | c.1113A>C p.S371= | Silent (SNP) | VAF 26/174 reads (15%) | catalogued as COSV99472906; called by muse, mutect2, varscan2
- TMCO4 | c.1089C>T p.A363= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV99616414; called by muse, mutect2, varscan2
- TRMT13 | c.489C>T p.H163= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as COSV100924008; called by muse, mutect2, varscan2
- TSSK1B | c.939G>A p.E313= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs746229954, COSV101181049; called by muse, mutect2, varscan2
- TTC27 | c.546A>G p.P182= | Silent (SNP) | VAF 27/175 reads (15%) | catalogued as rs201745073, COSV100512924; called by muse, mutect2, varscan2
- TTN | c.100722T>C p.T33574= (on ENST00000591111; = p.T26150= on NM_003319.4) | Silent (SNP) | VAF 49/302 reads (16%) | catalogued as COSV100608794; called by muse, mutect2, varscan2
- TTN | c.37806G>A p.V12602= (on ENST00000591111; = p.V5178= on NM_003319.4) | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV100608799; called by muse, mutect2, varscan2
- TTN | c.18138C>A p.T6046= (on ENST00000591111; = p.T5119= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100608806; called by muse, mutect2, varscan2
- TTN | c.17604C>A p.G5868= (on ENST00000591111; = p.G4941= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/191 reads (14%) | catalogued as COSV100608810; called by muse, mutect2, varscan2
- UGT1A9 | c.684A>G p.L228= | Silent (SNP) | VAF 72/458 reads (16%) | catalogued as rs146422336; called by muse, mutect2, varscan2
- UNC79 | c.3477T>A p.P1159= (on ENST00000393151 / NM_001346218.2; = p.P982= on NM_020818.5) | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV99827419; called by muse, mutect2, varscan2
- USH2A | c.12402C>A p.A4134= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100233353; called by muse, mutect2, varscan2
- WDR3 | c.1698G>T p.V566= | Silent (SNP) | VAF 49/300 reads (16%) | catalogued as COSV100308816; called by muse, mutect2, varscan2
- ZNF71 | c.1329C>T p.C443= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV60150998; called by muse, mutect2, varscan2
- ZRANB2 | c.759G>T p.G253= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV54675537; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840726 C>G | 5'Flank (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100006248, COSV100008039; called by mutect2, varscan2
- DENND10P1 | n.1144A>T | RNA (SNP) | VAF 31/112 reads (28%) | called by muse, mutect2, varscan2
- KNOP1P1 | n.561G>T | RNA (SNP) | VAF 24/177 reads (14%) | catalogued as rs764834329; called by muse, mutect2, varscan2
- LEKR1 | c.*1479C>G | 3'UTR (SNP) | VAF 53/185 reads (29%) | catalogued as COSV100738849, COSV100739263; called by muse, mutect2, varscan2
- LINC02694 | n.365G>A | RNA (SNP) | VAF 12/93 reads (13%) | catalogued as COSV100601908; called by muse, mutect2, varscan2
- RUSC1 | c.-167del | 5'UTR (DEL) | VAF 5/26 reads (19%) | catalogued as COSV99430095; called by mutect2, pindel, varscan2
- SENP1 | c.221-287G>A | Intron (SNP) | VAF 14/84 reads (17%) | catalogued as COSV99136890; called by muse, mutect2
- SLC22A20P | n.592A>T | RNA (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
